EXCEPTIONAL_RESPONDERS case ER-AFAH — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d90526ef-3110-4979-a388-55c77a0c8553

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Alive.

Diagnoses (2)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.3 years (17,659 days); AJCC pathologic stage: Stage I.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,755 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Days to last follow up: 1,653 days (4.5 years); Days to best overall response: 407 days (1.1 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium; Days to treatment start: 29 days; Days to treatment end: 365 days (1.0 years).
   Treatment given: Therapeutic agents: Oxaliplatin; Days to treatment start: 29 days; Days to treatment end: 174 days.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 97 days; Days to treatment end: 372 days (1.0 years).
   Treatment given: Therapeutic agents: Irinotecan; Days to treatment start: 218 days; Days to treatment end: 365 days (1.0 years).

Follow-up (1 entry)
- Days to follow up: 1,653 days (4.5 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 1,653 days (4.5 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AFAH-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample ER-AFAH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AFAH-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 40; Percent normal cells: 10; Percent necrosis: 20; Percent stromal cells: 35; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
